Somatic mutation profile of tumor specimen MP2PRT-PARVFG-TBP1-A (aliquot MP2PRT-PARVFG-TBP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PARVFG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,064 days).
Specimen MP2PRT-PARVFG-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bc40d6d-09cc-455b-91b9-f3bde9ff4020.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARVFG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARVFG-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6481bef-0d9d-4e82-a569-e8c2b64c464e

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2525A>G p.Y842C | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376588714, COSV54044083; ClinVar: likely pathogenic; called by mutect2, varscan2
- PTPN11 | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 161/518 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP6V1B1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 123/257 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs727505222, CM990268, COSV52268223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTNL9 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 46/669 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs927944317; called by muse, mutect2
- CIDEA | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 139/444 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.88); catalogued as rs372580595; called by muse, mutect2, varscan2
- FAM47B | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 40/642 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs375171840, COSV61453160; called by muse, mutect2
- GTPBP2 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 37/492 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs748852772; called by muse, mutect2
- LRRTM4 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 174/334 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV101297705; called by muse, mutect2, varscan2
- MYH14 | c.4187G>A p.R1396H | Missense Mutation (SNP) | VAF 27/361 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs766518836; called by muse, mutect2
- NOC3L | c.16A>G p.N6D | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.079); catalogued as rs1162409867; called by muse, mutect2, varscan2
- TLN2 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.324); catalogued as rs781350490; called by muse, mutect2
- ZNF157 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 127/638 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs752927092, COSV65658921; called by muse, mutect2, varscan2
- CFAP46 | c.6703G>T p.A2235S | Missense Mutation (SNP) | VAF 24/606 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.068); called by muse, mutect2
- ODF2L | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, varscan2
- PADI2 | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 111/263 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- VPS4B | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 115/375 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLSTN3 | c.1215C>T p.D405= | Silent (SNP) | VAF 76/216 reads (35%) | catalogued as rs368707350; called by muse, mutect2, varscan2
- FTMT | c.150C>G p.A50= | Silent (SNP) | VAF 213/456 reads (47%) | catalogued as rs747293035, COSV58419675; called by muse, mutect2, varscan2
- SYNCRIP | c.627T>C p.T209= | Silent (SNP) | VAF 30/434 reads (7%) | called by muse, mutect2
- CCDC40 | c.1562+2005G>A | Intron (SNP) | VAF 123/459 reads (27%) | catalogued as rs544228027; called by muse, mutect2, varscan2
